Somatic mutation profile of tumor specimen HCM-WCMC-0673-C56-86A (aliquot HCM-WCMC-0673-C56-86A-01D-A937-36) from HCMI case HCM-WCMC-0673-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIA2; FIGO stage: Stage III; Age at diagnosis: 32.9 years (12,015 days).
Specimen HCM-WCMC-0673-C56-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f04c8aab-6c47-4d74-95f9-289bba9c4f71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0673-C56-10A (Blood Derived Normal), aliquot HCM-WCMC-0673-C56-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af9ce608-6c9e-4c51-8cc2-ebf46c8fc67b

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 184/394 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SMAD4 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 177/178 reads (99%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.869del p.R290Pfs*55 | Frame Shift Del (DEL) | VAF 290/402 reads (72%) | hotspot (GDC flag); catalogued as CM065493, CM993905, COSV52683585, COSV53296796; called by mutect2, pindel, varscan2
- AIFM2 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 208/438 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs750119679, COSV100325838; called by muse, mutect2, varscan2
- MACROD2 | c.1171G>A p.V391M (on ENST00000642719; = p.V363M on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/510 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs142381393; called by muse, mutect2
- METTL8 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 188/408 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754629409; called by muse, mutect2, varscan2
- NLGN4X | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 304/899 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs758529208, COSV52003690; called by muse, mutect2, varscan2
- SLFN14 | c.122A>C p.E41A | Missense Mutation (SNP) | VAF 44/763 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs1233366270; called by muse, mutect2
- SNX13 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 38/514 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs750665982, COSV68068652; called by muse, mutect2
- ULK3 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 285/549 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1018512142; called by muse, mutect2, varscan2
- ZNF423 | c.3119C>T p.T1040M (on ENST00000563137 / NM_001379286.1; = p.T1032M on NM_015069.4) | Missense Mutation (SNP) | VAF 68/617 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.37); catalogued as rs371313827; called by muse, mutect2, varscan2
- ABCC2 | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 201/391 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ALPK1 | c.407A>C p.K136T | Missense Mutation (SNP) | VAF 54/598 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2
- ATP1A2 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 144/327 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- BCL11B | c.1934C>T p.A645V (on ENST00000357195 / NM_001282237.2; = p.A574V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, varscan2
- CCDC88A | c.2690C>T p.A897V | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDKN2A | c.263_264del p.E88Gfs*31 | Frame Shift Del (DEL) | VAF 435/583 reads (75%) | called by mutect2, pindel, varscan2
- CTSG | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 214/646 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LARS1 | c.1284+1G>T p.X428_splice (on ENST00000394434 / NM_020117.11; = p.X401_splice on NM_016460.3) | Splice Site (SNP) | VAF 136/305 reads (45%) | called by muse, mutect2, varscan2
- OXSR1 | c.857T>G p.L286* | Nonsense Mutation (SNP) | VAF 163/458 reads (36%) | called by muse, mutect2, varscan2
- PLEK | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- PRSS54 | c.1030G>C p.G344R | Missense Mutation (SNP) | VAF 325/672 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SECISBP2 | c.2402C>T p.P801L | Missense Mutation (SNP) | VAF 24/698 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- CECR2 | c.3327A>G p.E1109= (on ENST00000342247 / NM_001290047.2; = p.E925= on NM_001290046.1) | Silent (SNP) | VAF 57/800 reads (7%) | called by muse, mutect2
- GPRC5B | c.498G>A p.A166= | Silent (SNP) | VAF 226/762 reads (30%) | catalogued as rs1288522295; called by muse, mutect2, varscan2
- MOV10 | c.2019G>A p.G673= | Silent (SNP) | VAF 60/569 reads (11%) | called by muse, mutect2, varscan2
- SLC26A3 | c.138C>T p.S46= | Silent (SNP) | VAF 175/368 reads (48%) | catalogued as rs750358656; called by muse, varscan2
- FUT9 | c.*7911A>G | 3'UTR (SNP) | VAF 239/511 reads (47%) | catalogued as COSV100133553; called by muse, mutect2, varscan2
- PRB3 | c.605-28A>C | Intron (SNP) | VAF 8/71 reads (11%) | catalogued as rs770486309, COSV54388034; called by muse, varscan2
